TCGA case TCGA-IB-AAUQ — Pancreatic Adenocarcinoma (TCGA-PAAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas; Tissue source site: Alberta Health Services. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/afe89625-b355-454d-8c0b-b4161edd69f8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 50 years; Vital status: Dead; Days to death: 183 days; Cause of death: Cancer Related; Cause of death source: Medical Record.

Diagnoses (2)
1. Infiltrating duct carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.2; Tissue or organ of origin: Tail of pancreas; Site of resection or biopsy: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 50.1 years (18,315 days); Year of diagnosis: 2013; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 183 days; Sites of involvement: Pancreas Tail.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 13; Lymph nodes tested: 21; Tumor largest dimension diameter: 4.5 cm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan + Oxaliplatin; Days to treatment start: 135 days; Days to treatment end: 169 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Distal Pancreatectomy.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Infiltrating duct carcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 50.4 years (18,422 days); Days to diagnosis: 107 days; Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 107 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (2 entries)
- Day 107 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 107 days; Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 183 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 69; Tobacco smoking onset year: 1978; Tobacco smoking quit year: 2001.
- Alcohol history: Yes; Alcohol intensity: Social Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-IB-AAUQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 240 mg.
  Slide TCGA-IB-AAUQ-01A-02-TSB: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 40; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-IB-AAUQ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-IB-AAUQ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Invasive adenocarcinoma indicator: Yes; Histologic diagnosis: Pancreas-Adenocarcinoma Ductal Type; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Lymph nodes examined: Yes; Tumor status: With tumor; Tobacco smoking history indicator: 4; Diabetes diagnosis indicator: No; History chronic pancreatitis: No; Treatment outcome first course: Partial Remission/Response.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Cause of death: Pancreatic Cancer.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 183 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 183 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 107 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-IB-AAUQ-01A-22D-A40V-01): tumor purity 0.26, ploidy 1.92, whole-genome doublings 0.
